Somatic mutation profile of tumor specimen TCGA-EL-A3GS-01A (aliquot TCGA-EL-A3GS-01A-11D-A20C-08) from TCGA case TCGA-EL-A3GS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.1 years (13,542 days).
Specimen TCGA-EL-A3GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c529c06-9ec7-4913-8bf9-90f8c8e29e5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GS-10A (Blood Derived Normal), aliquot TCGA-EL-A3GS-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df4775e0-180c-4dde-a3d5-b906c00cae8b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHST5 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1355660430, COSV60341821; called by muse, mutect2, varscan2
- DYRK4 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.21); catalogued as COSV50545567; called by muse, mutect2, varscan2
- PCDHGC4 | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs765887978, COSV52769728; called by muse, mutect2, varscan2
- SDC4 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65596124; called by muse, mutect2, varscan2
- ZNF280C | c.1398A>T p.K466N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV63970001; called by muse, mutect2, varscan2
- FILIP1L | c.2658T>C p.F886= (on ENST00000354552 / NM_182909.3; = p.F646= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV58776624; called by muse, mutect2
- PIK3CG | c.2043G>A p.L681= | Silent (SNP) | VAF 15/222 reads (7%) | catalogued as COSV63254028; called by muse, mutect2
